Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A7WB, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A7WB-01A (Primary Tumor).

[page 1 of 2]
---SURGICAL PATHOLOGY CONSULTATION--- (Accession

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

A. Uterus, hysterectomy:

Myometrium:

Leiomyosarcoma, grade 2, 10.1 cm in greatest dimension, present at the serosal surface.

Vascular space invasion identified.

Adenomyosis.

Cervix:

No diagnostic abnormality.

Endometrium:

Inactive endometrium.

B. Ovary and fallopian tube, right salpingo-oophorectomy:

Ovary:

No diagnostic abnormality.

Fallopian tube:

No diagnostic abnormality.

C. Ovary and fallopian tube, left, salpingo-oophorectomy:

Ovary:

No diagnostic abnormality.

Fallopian tube:

No diagnostic abnormality.

D. Soft tissue, "tumor", excision:

Leiomyosarcoma.

E. Soft tissue, posterior cul-de-sac, excision:

Leiomyosarcoma.

F. Soft tissue, posterior cul-de-sac #2, excision:

Fibroadiipose tissue.

No tumor identified.

G. Soft tissue, left posterior cul-de-sac, excision:

Leiomyosarcoma.

H. Omentum, omentectomy:

Fibroadiipose tissue.

No tumor identified.

Date reported:

Pathologist (Electronic Signature)

HISTORY

TISSUE SUBMITTED

A. Uterus and cervix

B. Right ovary and tube

C. Left ovary and tube

D. Tumor

E. Posterior cul de sac

F. Posterior cul de sac #2

G. Left posterior cul de sac

H. Omentum

GROSS

A. Specimen includes: Received fresh in a container labeled with patient's name, hospital number, and "uterus and cervix".

Uterine size and weight: 560 grams; 9.9 cm cornu to cornu; 7.6 cm anterior to posterior; 21.9 cm cervix to fundus.

Cervix size: 2.4 x 3.1 cm with a 0.9 cm slit-like os.

Adnexa (right and left): See other parts.

Tumor gross morphologic description: The tumor consists of a pink-tan-red fleshy firm whorled mass involving the anterior and posterior uterine cavity. It extends the full thickness of the myometrium.

Overall size: 10.1 x 9.5 x 9.1 cm.

Location(s) grossly involved: The mass involves both anterior and posterior myometrium.

Depth of invasion: The mass invades the full thickness myometrium.

Endometrial thickness: <0.1 cm.

Serosal involvement: The mass appears to extend through the serosal surface, on the posterior side.

Cervix involvement: Grossly uninvolved.

Adnexal involvement: See other parts.

ICD-O-3

Leiomyosarcoma NOS 8890/3

C55.9

Site Uterus NOS C55.9

path

Myometrium C54.2

JA 10/10/13

[page 2 of 2]
Other findings: The uninvolved myometrium is pink-tan and trabeculated. The endometrium is red-tan and thin with a slightly roughened surface. Blocks submitted: A1, anterior cervix; A2, posterior cervix; A3, anterior lower uterine segment; A4, posterior lower uterine segment; A5, uninvolved anterior endomyometrium; A6, posterior endomyometrium with segment of tumor; A7, posterior endomyometrium with endometrium abutting tumor; A8, anterior endometrium overlying tumor; A9, tumor at resection margin, adjacent to anterior lower uterine segment; A10, anterior endomyometrium with tumor and possible lymphovascular space invasion; A11, posterior endomyometrium invading through serosal surface. Photograph: None.

B. Received in formalin in a container labeled with the patient's name, hospital number and "Right ovary and tube" is a 4.2 x 3.6 x 1.3 cm attached ovary, fallopian tube and soft tissue. The fallopian tube is 2.9 cm in length x 0.6 cm in diameter with a pink-tan, smooth and glistening surface. The ovary is 2.5 x 1.6 x 1.1 cm, yellow-pink and cerebriform. Sectioning the fallopian tube reveals pink-tan cut surfaces and a 0.1 cm lumen. Sectioning the ovary reveals tan-pink cut surfaces. B1, section of fallopian tube and ovary.

C. Received in formalin in a container labeled with the patient's name, hospital number and "Left ovary and tube" is a 3.5 x 2.6 x 1.5 cm segment of soft tissue with fallopian tube, ovary and attached soft tissue. The fallopian tube is 3.5 cm in length x 0.6 cm in diameter with a red-tan, smooth and glistening surface. The ovary is 2.1 x 1.5 x 1.4 cm in dimension and has a pink-tan cerebriform surface. Sectioning of the fallopian tube reveals tan cut surfaces and a 0.1 cm lumen. Sectioning the ovary reveals tan-white cut surfaces. C1, segments of tube and ovary.

D. Received in formalin in a container labeled with the patient's name, hospital number and "Tumor" is a 2.0 x 0.9 x 0.5 cm segment of red, yellow, previously bisected soft tissue. The specimens are submitted entirely in D1. E. Received in formalin in a container labeled with the patient's name, hospital number and "Posterior cul de sac" is a 6.4 x 2.4 x 1.9 cm segment of pink-red, friable soft tissue. The specimen is serially sectioned and entirely submitted in E1-E7.

F. Received in formalin in a container labeled with the patient's name, hospital number and "Posterior cul de sac #2" is a 3.4 x 2.8 x 1.2 cm segment of red-pink soft tissue with a smooth and glistening surface. Focal areas of cautery are present. The specimen is sectioned revealing pink-red cut surfaces. The specimen is entirely submitted in F1-F4.

G1-G5. H. Received in formalin in a container labeled with the patient's name, hospital number and "Omentum" is a 49.5 x 16.6 x 1.8 cm yellow-red, lobulated segment of omentum. No discrete masses are identified. Sectioning reveals yellow-red, lobulated cut surfaces. Representative sections are submitted in H1-H3.

MICROSCOPIC

A. Microscopic examination performed and supports the diagnosis.

Pathologic Primary Tumor (T)

DEFINITIONS

TNM FIGO Definitions

XX T2b IIIA Tumor involves other pelvic tissues

Pathologic Regional Lymph Nodes (N)

XX NX Regional lymph nodes cannot be assessed

The pathologic stage based on available pathologic material is: T2b NX

B-H. Microscopic examination performed and supports the diagnosis.

Performed by:

As the primary pathologist on this case, I have personally reviewed this case and edited the report as necessary.

Lab and Collection

--SURGICAL PATHOLOGY CONSULTATION-- (Order

Collection Information

Result History

--SURGICAL PATHOLOGY CONSULTATION-- (Order

Order Result History Report

Result Entered By

Lab Information

Source: NCI Genomic Data Commons file d6c51a11-7d55-408e-9fdb-0688ecf022ad (TCGA-X6-A7WB.546B8584-6995-45E3-B83C-C8DB1FA9301E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).